Somatic mutation profile of tumor specimen 0DMWTR from CCDI case PBCAIK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.9 years (2,513 days).
Specimen 0DMWTR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e53e503b-af95-411c-b3bc-2f861f035a95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMWTX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51cb37f6-b9d0-45db-8035-e736492d6034

The open-access MAF lists 28 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 6, Silent 4, 3'UTR 3, 5'UTR 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 402/1582 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs148771698, COSV55394322; ClinVar: uncertain significance; called by muse, varscan2
- MAP1B | c.2305G>C p.D769H | Missense Mutation (SNP) | VAF 630/1362 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV99702278; called by muse, mutect2, varscan2
- MYLK | c.3899C>T p.A1300V | Missense Mutation (SNP) | VAF 381/837 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.254); catalogued as rs201265306, COSV60612429; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEURL4 | c.3445C>T p.R1149C | Missense Mutation (SNP) | VAF 251/281 reads (89%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.568); catalogued as rs769725643, COSV59750254; called by muse, mutect2, varscan2
- PCDH9 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 336/729 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV60528844; called by muse, mutect2, varscan2
- SNAP29 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 132/512 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs752535047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCF1 | c.1672_1674del p.L558del (on ENST00000326195 / NM_001025091.2; = p.L520del on NM_001090.3) | In Frame Del (DEL) | VAF 236/624 reads (38%) | called by mutect2, varscan2
- ATP1A1 | c.1148dup p.N384Efs*11 | Frame Shift Ins (INS) | VAF 466/986 reads (47%) | called by mutect2, varscan2
- LAMB2 | c.2765G>T p.G922V | Missense Mutation (SNP) | VAF 38/858 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- MPHOSPH9 | c.2652A>G p.I884M | Missense Mutation (SNP) | VAF 44/1570 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2
- PRKCQ | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 210/496 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- PRRC2A | c.4775C>T p.P1592L | Missense Mutation (SNP) | VAF 37/1278 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- RASL11A | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 65/1024 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDRT15L2 | c.27G>A p.S9= | Silent (SNP) | VAF 451/831 reads (54%) | catalogued as rs764629807; called by muse, varscan2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 20/386 reads (5%) | called by muse, mutect2
- PRRC2A | c.4776A>G p.P1592= | Silent (SNP) | VAF 37/1269 reads (3%) | called by muse, mutect2
- RNF146 | c.978A>T p.S326= (on ENST00000368314 / NM_001242850.2; = p.S325= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 88/1492 reads (6%) | catalogued as rs770171920; called by muse, mutect2
- ABLIM1 | c.-92T>C | 5'UTR (SNP) | VAF 69/136 reads (51%) | called by muse, mutect2, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 17/121 reads (14%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 42/304 reads (14%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 42/296 reads (14%) | called by muse, varscan2
- DPM3 | c.-32+85G>C | Intron (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- LILRB1 | c.*34A>C | 3'UTR (SNP) | VAF 140/272 reads (51%) | called by muse, mutect2
- MAP3K12 | c.*57C>T | 3'UTR (SNP) | VAF 13/120 reads (11%) | catalogued as rs1018838665, COSV99913570; called by muse, varscan2
- PTCH1 | c.3449+89A>G | Intron (SNP) | VAF 23/264 reads (9%) | catalogued as COSV100109080; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 32/270 reads (12%) | called by muse, varscan2
- SLC14A1 | c.-21-89C>A | Intron (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 10/76 reads (13%) | called by muse, varscan2
